Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAQ2, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAQ2-01A (Primary Tumor).

[page 1 of 4]
TSS Patient ID:

Surgical Date:

Gross Description: A: Lymph node of gastroduodenal artery: Received is 1 unoriented, irregular, yellow to red, fatty tissue, measuring 3 x 1.5 x 1 cm, with adjacent red-brown, soft tissue. The specimen is bisected. The entire specimen is submitted.

B: in subtotal gastrectomy: Received weighing 910 grams, consisting of stomach, pancreas with tumor, spleen, as well as attached fat. The pancreas with tumor measures 11 (ML) x 5 (SI) x 5 (AP) cm. The tumor is inked black, the staple line is removed, and inked orange. The tumor has been bisected and noted to be 1.2 cm to the margin. The entire pancreatic margin was sent for frozen section diagnosis. Underlying tissue is inked orange. The mass measures 5.5 (ML) x 4.5 (SI) x 4.5 (AP) cm, indurated, ovoid, light tan with central yellow necrosis. The mass invades the gastric wall and is located 2.5 cm to proximal and 15 cm to distal margins. The spleen measures 12 (SI) x 7 (AP) x 3 (ML) cm and has an intact capsule. The stomach measures 22 x 11 x 3 cm. There is a proximal staple line measuring 12 cm and a distal staple line measuring 3.5 cm adjacent to pylorus. The greater curvature measures 28 cm and the lesser curvature measures 15 cm. A portion of the tumor is sent to

. Representative sections are submitted.

C: Pancreatic margin: Received are multiple tissues measuring 3 x 2 x 0.7 cm. There is a blue surgical stitch indicated as new surgical margin. The frozen section residue is submitted.

ICD-O-3
adenocarcinoma, duct NOS 8560/3
path
Carcinoma, neuroendocrine NOS 8446/3
Site: Pancreas-head C85.0
Q1 5/16/14

[page 2 of 4]
Microscopic Description:

Diagnosis Details: Specimen: Head of pancreas, Stomach, Spleen

Procedure: Pancreaticoduodenectomy (Whipple resection), partial pancreatectomy

Tumor Site: Pancreatic head

Tumor size greatest dimension: 5.5cm

Tumor Focality: Unifocal

Histologic Type: Poorly differentiated endocrine carcinoma

Mitotic Activity: Cannot be determined

Microscopic Tumor Extension: Tumor invades other adjacent organs or structures: gastric wall and blood vessels

Margins: Negative for tumor

Angiolymphatic Invasion: Present

Perineural Invasion: Present

AJCC Stage (7th Edition) (pTNM)

Primary Tumor (pT): pTX

Regional Lymph Nodes (pN): pN1

Number of regional lymph nodes involved: 2

Number of regional lymph nodes examined: 23

Distant Metastasis (pM): Not applicable

Comments: Comment: The involved lymph nodes are immediately adjacent to the tumor mass; therefore the involvement of the nodes may be by direct extension instead of or in addition to lymphatic spread.

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Whipple resection

Tumor site: Head

Tumor size: 5.5 cm

Histologic type: Adenocarcinoma, ductal type

[page 3 of 4]
Histologic grade: Poorly differentiated

Tumor extent: Other - Other surrounding organs

Lymph nodes: 2/23 positive for metastasis (Regional 2/23)

Lymphatic invasion: Present

Venous invasion: Present

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

*Per TSS dx discrepancy form,
TCGA tumor is adenocarcinoma,
ductal type.*

for 2/11/14

Diagnosis Discrepancy	Pathdis form	✓

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on _____) Completed Date: _____

Diagnosis Information			
#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Poorly differentiated endocrine carcinoma	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Adenocarcinoma, ductal type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form			
3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Pathology report says "Endocrine carcinoma," but review by site pathologist has found Adenocarcinoma, ductal type. The tumor is poorly differentiated.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator signature

Date

Source: NCI Genomic Data Commons file 51a9869d-852f-4bc8-b5ae-842a14d498b5 (TCGA-FB-AAQ2.10BE4376-2ED6-43BA-B542-9F3E96419BB9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).